TCGA case TCGA-DK-A3IN — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fc0032db-b6d8-4da3-bd1b-beec4196abf0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 250 days.

Diagnoses (4)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.2; Tissue or organ of origin: Lateral wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 72.7 years (26,562 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 250 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 14.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Abdomen, NOS; Laterality: Right; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Esophagus, NOS; Classification of tumor: Prior primary; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2a.

Follow-up (2 entries)
- Days to follow up: 250 days; Disease response: Tumor Free.
- Karnofsky performance status: 80.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 107.5 kg; Height: 182.5 cm; BMI: 32.3.

Exposures
- Occupation duration years: 49; Occupation type: Machinery Mechanics and Repairers.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 40; Tobacco smoking quit year: 1986.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Cancer.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DK-A3IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,020 mg.
  Slide TCGA-DK-A3IN-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DK-A3IN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DK-A3IN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: Mechanic; Occupation primary: Mechanic; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Wall Lateral; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2a.
- Stage record, Gleason grading: Gleason score: 6.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Other malignancy anatomic site: Abdomen; Other malignancy histological type: Basal Cell Carcinoma.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: 84.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Esophagus; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: 152.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Patient had synchronous prostate cancer. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 250 days; disease-specific survival: no event (censored), 250 days; disease-free interval: no event (censored), 250 days; progression-free interval: no event (censored), 250 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DK-A3IN-01A-11D-A20B-01): tumor purity 0.39, ploidy 3.57, whole-genome doublings 1.
